Gene-level copy-number profile of tumor specimen HTMCP-03-06-02230-01A from CGCI case HTMCP-03-06-02230, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3.
Specimen HTMCP-03-06-02230-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eb064c3c-d776-44dd-8f12-d73828972ff0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02230-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/29e08822-61f4-4efd-89f5-a929aaa478d3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 6,858; copy number 3: 29,689; copy number 4: 13,822; copy number 5: 7,860; copy number 6: 8; copy number 7: 44; copy number 8: 12; copy number 9: 12; copy number 10: 35; copy number 13: 5; copy number 101: 10; copy number 111: 4; copy number 112: 33.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 155 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:226,731,317–226,813,741, 3 genes, copy number 8: IRS1, AC010735.2, AC010735.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 8: TRGC2.
- chr7:38,257,879–38,335,514, 13 genes, copy number 8–13: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:142,507,382–142,793,368, 43 genes, copy number 7: TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 7: TRBC2.
- chr10:120,354,701–123,058,290, 47 genes, copy number 101–112: RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB.
- chr14:22,132,553–22,492,907, 46 genes, copy number 9–10: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47.
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
